Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-B1PV, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-B1PV-TTP1-A (Slides).

[page 1 of 10]
Specimen #:

Ordering Doctor:

Received Date:

Collection Date:

+0

+0

DIAGNOSIS

RIGHT BREAST, CORE NEEDLE BIOPSY:

INFILTRATING CARCINOMA:

HISTOLOGIC TYPE: DUCTAL

MODIFIED BLOOM-RICHARDSON GRADE: 3/3 (A 3 N 2 M 3)

ASSOCIATED IN-SITU COMPONENT: NO

MICROCALCIFICATIONS: NO

LYMPHOVASCULAR INVASION: NO

ESTROGEN RECEPTOR: POSITIVE (80% CELLS IMMUNOREACTIVE)

PROGESTERONE RECEPTOR: POSITIVE (80% CELLS IMMUNOREACTIVE)

Ki-67 PROLIFERATION MARKER: 90% OF CELLS IMMUNOREACTIVE

HER2 OVEREXPRESSION (FISH): POSITIVE

CLINICAL INFORMATION:

PREOPERATIVE DIAGNOSIS: ABN NODULE

POSTOPERATIVE DIAGNOSIS: NOT PROVIDED

SPECIMEN(S): A. BREAST NEEDLE CORE BX - RIGHT BREAST, ABN NODULE

GROSS DESCRIPTION:

Received in formalin are 3 cylindrical segments of white-yellow tissue, the largest one measuring 1.3 CM in length and 0.1 CM in diameter. All tissue is submitted in one cassette. The requisition indicates specimen collection time of [REDACTED] No formalin fixation time is provided.

MICROSCOPIC EXAMINATION:

Microscopic examination of all tissue submitted (as indicated in the gross description) is performed, the findings of which are summarized in the final diagnosis.

[REDACTED] has reviewed a representative slide and concurs with the interpretation.

ESTROGEN/PROGESTERONE RECEPTOR ANALYSIS BY IMMUNOHISTOCHEMISTRY:

PATIENT RESULTS:

ER: 80% OF CELLS POSITIVE

INTENSITY OF STAINING: MODERATE

PR: 80% OF CELLS POSITIVE

INTENSITY OF STAINING: MODERATE

SURGICAL PATHOLOGY REPORT

[page 2 of 10]
SPEC # [REDACTED]

PATIENT [REDACTED]

(Continued)

GROSS/MICROSCOPIC DESCRIPTION: (Continued)

Internal positive control: YES

External positive and negative controls show appropriate reactivity.

Grading Criteria For Estrogen/Progesterone Receptor Assay.*Negative: Less than 1% of nuclei staining**Positive: Greater than or equal to 1% of nuclei staining*

The tissue was fixed in 10% neutral buffered formalin for a minimum of 6 and maximum of 48 hours. Positive and negative control cases, as well as benign tissue in the formalin-fixed tissue block (if present) are used as quality controls. Detection method: DAB Copper Chromogen. ER Clone: SP1. PR Clone: 1E2.

HER2 BY FLUORESCENCE IN SITU HYBRIDIZATION (FISH): POSITIVE

Along with fluorescence in situ hybridization (FISH), an H&E stained slide was reviewed by a pathologist to identify the target area containing invasive tumor. FISH analysis of 40 interphase nuclei was performed within the marked target area using a dual-probe FISH assay [REDACTED]. Controls performed appropriately.

Results show a HER2 to centromere 17 ratio of ≥ 2.0 and an average HER2 copy number ≥ 4.0 signals per cell following a HER2 breast FISH protocol. (Patient ratio is 5.1; number of copies: 17.8). This is a POSITIVE result according to the 2013 ASCO/CAP guidelines.

Reference: Wolff AC, Hammond MEH, Hicks DG, et al. Recommendations for Human Epidermal Growth Factor Receptor 2 Testing in Breast Cancer. Arch Pathol Lab Med. doi: 10.5858/arpa.2013-0953-SA.

Note: This HER2 FISH assay was scored on an automated image analysis platform. Two or more independent areas of tumor were analyzed and the technical results underwent a manual technologist review for quality control purposes.

The performance characteristics of the PathVysion kit and the technical component of this test were performed by [REDACTED]

Pathologist: [REDACTED]

+1

SURGICAL PATHOLOGY REPORT

[page 3 of 10]
[REDACTED]

[REDACTED]

MyChart Results Release

MyChart Status: Active

Patient Release Status:

This result is viewable by the patient in MyChart.

[REDACTED] +24

Procedure: CT CHEST, ABDOMEN & PELVIS WITH IV CONTRAST
Exam Date & Time: [REDACTED] +21
Status: Final

Patient: [REDACTED]
DOB: [REDACTED]
Sex: [REDACTED]
Pt Class: [REDACTED]
Location: [REDACTED]

MRN #: [REDACTED]
Order #: [REDACTED]
Accession #: [REDACTED]
Ord Prov: [REDACTED]

NARRATIVE:

CT CHEST, ABDOMEN, AND PELVIS WITH CONTRAST.

DATE: [REDACTED] +21

CLINICAL HISTORY: Breast cancer.

COMPARISON: None

TECHNIQUE: After the administration of oral contrast and dynamic intravenous infusion of 125 milliliters of Isovue 370 contiguous 3 mm acquisition of the chest and 5 mm through the abdomen and pelvis were performed during postcontrast and delayed phases. Axial MIP and sagittal reformatted images of the chest as well as coronal reformatted images of the chest, abdomen and pelvis were generated.

The CT scan was performed with attention to patient radiation dose reduction, as low as reasonably achievable (ALARA), while maintaining diagnostic image quality. This includes appropriate physician-selected protocols to tailor the exam for minimum exposure. Breast shielding was utilized.

FINDINGS:

[page 4 of 10]
[REDACTED]

CHEST: There is an obliquely oriented soft tissue mass, with the nodular, irregular enhancement within the right breast. Measurements are difficult due its configuration. It is at least 1.7 x 3.6 cm in maximal transaxial dimensions on image 46/2, and 1.8 cm in craniocaudal dimension on sagittal image 11/80534. There is stranding, extending to a 1.6 cm segment of the anterior chest wall on image 44/two, which could represent chest wall invasion. Two large left hilar lymph nodes are seen, one of which measures 1.6 x 2.2 cm on image 38/2. Prominent prevascular, nonenlarged lymph nodes are seen. The left breast appears normal.

There are multiple, lobulated noncalcified nodules and masses within the left upper and lower lobes, the largest abuts the anterior mediastinum, measuring 2.3 x 5.1 cm on image 35/4. Several, subcentimeter satellite nodules are seen. A large nodule in the left lingula measures 2.7 x 2.8 cm on image 59/4. A nodule abutting the major fissure at the superior left lower lobe measures 0.9 x 1.5 cm. The central airways are patent. No pleural effusions are seen. Right lung is clear.

Thyroid appears normal. The heart size is normal. There is no pericardial effusion. The thoracic aorta is non-aneurysmal. Main pulmonary arteries are not enlarged.

No destructive osseous lesions are seen.

ABDOMEN/PELVIS: The liver, gallbladder, pancreas, spleen, and adrenal glands appear normal. The kidneys appear normal and function symmetrically. Renal collecting systems are nondilated.

The stomach is partially distended with fluid and gas, and is otherwise unremarkable. There are no dilated loops of bowel. No free intra-abdominal air or fluid collection is seen. There are no enlarged mesenteric lymph nodes.

The abdominal aorta is non-aneurysmal. Accessory right renal arteries are noted. No IVC filling defect is seen. There are no enlarged retroperitoneal or pelvic lymph nodes. The urinary bladder is partially distended and thin-walled. The uterus is unremarkable. No suspicious adnexal masses are seen.

No destructive osseous lesions. Subcutaneous soft tissues are unremarkable.
IMPRESSION:

1. Lobulated nodular enhancing right breast mass compatible with provided diagnosis of a breast cancer. Possible invasion of the chest wall.
2. Multiple, enhancing left lung pulmonary nodules with a dominant mass in the left upper lobe abutting the mediastinum, and enlarged left hilar lymph nodes. This is suggestive of metastatic disease, although synchronous primary lung cancer cannot be excluded given the distribution of involvement.
3. No osseous metastasis.

Findings were verbally discussed over the phone with [REDACTED] at [REDACTED]
hrs [REDACTED] +21

[page 5 of 10]
[REDACTED]

[REDACTED]

MyChart Results Release

MyChart Status: Active

Patient Release Status:

This result is viewable by the patient in MyChart.

Last viewed in MyChart:

[REDACTED] +105

By:

[REDACTED] +106

[REDACTED] +106

Procedure:

CT CHEST, ABDOMEN & PELVIS WITH IV CONTRAST

Exam Date & Time:

[REDACTED] +100

Status:

Final

Patient:

DOB:

Sex:

Pt Class:

Location:

MRN #:

Order #:

Accession #:

Ord Prov:

NARRATIVE:

EXAM:

CT CHEST, ABDOMEN AND PELVIS WITH IV CONTRAST

[REDACTED] +100

HISTORY:

[REDACTED] female with Malignant neoplasm of breast (female), unspecified site. Per medical record, the patient has been on chemotherapy and is status post left lower lobe wedge resection [REDACTED] +29

COMPARISON:

[REDACTED] +21

TECHNIQUE:

Following the ingestion of oral contrast, during dynamic infusion of 125 mL of Isovue 370, contiguous 3 mm sections were obtained through the chest with 5 mm sections through the abdomen and pelvis. Additional longitudinal reformatted images were created. A nonionic contrast agent was used.

[page 6 of 10]
[REDACTED]

This CT scan was performed with attention to patient radiation dose reduction, as low as reasonably achievable (ALARA), while maintaining diagnostic imaging quality. This includes appropriate physician-selected protocols to tailor the examination for minimum exposure and utilization of an active dose reduction device according to body habitus.

FINDINGS:

+21

CHEST: In comparison to the prior study of [REDACTED] there is significant interval decrease in the size of the right breast mass with soft tissue density surrounding a calcific focus/biopsy clip measuring approximately 1.3 x 0.8 cm, difficult to distinguish from adjacent glandular tissue, previously approximately 3.6 x 1.9 cm. Previously seen extension adjacent to the pectoralis major muscle is no longer visualized. No enlarged axillary lymph nodes are visualized.

Subcentimeter in short axis prevascular nodes are stable and are not enlarged by size criteria. Previously seen enlarged left hilar lymph nodes have resolved. No new or enlarged supraclavicular, axillary, mediastinal, hilar, or internal mammary lymph nodes are identified. The thyroid gland is not enlarged.

The heart is normal in size. No pericardial effusion is noted. The main pulmonary artery is normal in caliber. Left-sided chest port with its tip at the right atrium.

Central airways are patent. No pleural effusion or pneumothorax. There is significant interval decrease in the size of previously seen left lung nodules/masses. Atelectasis in the right middle lobe. The right lung is otherwise clear. A part solid left upper lobe nodule (3/34) measures 1.1 x 0.8 cm, previously a solid nodule measuring 1.4 x 1.2 cm. A suture line along the left major fissure is compatible with wedge resection of the previously seen superior segment left lower lobe nodule adjacent to the fissure; no soft tissue nodularity is seen along the suture line. Left paramediastinal mass now measures 3.4 x 0.8 cm (3/35) with interval resolution of previously demonstrated satellite nodules, previously 4.8 x 2.5 cm. The lingular mass now measures 1.5 x 0.7 cm (3/68), previously 2.7 x 1.9 cm.

Bone windows demonstrate no suspicious blastic or lytic lesions. On sagittal reconstruction, the vertebral body heights are well-maintained. Degenerative changes are seen in the spine.

ABDOMEN AND PELVIS: The liver, spleen, gallbladder, pancreas and the adrenal glands have a normal CT appearance. There is no pancreatic or biliary ductal dilatation.

The kidneys appear normal. No hydronephrosis, renal calculi, focal mass lesions, or perinephric fluid collection.

Oral contrast has propagated to the rectum. The small and large bowel appear normal in caliber, without any apparent wall thickening. No enlarged lymph nodes are noted.

Imaging of the pelvis demonstrates a normal appearing urinary bladder. The uterus is present. There are no enlarged pelvic lymph nodes. No free fluid is noted in the pelvis.

The abdominal aorta is non-aneurysmal. The celiac, superior and inferior mesenteric arteries are patent at their origins.

Bone windows demonstrate no suspicious blastic or lytic lesions. On sagittal reconstructions, the vertebral body heights are well-maintained.

IMPRESSION:

[page 7 of 10]
- [REDACTED]
- [REDACTED]
1. Significant interval decrease in the size of right breast mass.
2. Significant interval decrease in the size of left lung nodules/masses. Postsurgical changes compatible with left lower lobe wedge resection. Interval resolution of the previously seen left hilar adenopathy.
3. No metastatic lesions in the abdomen or pelvis.

I, [REDACTED] have personally reviewed and interpreted the images of this study. In addition, I have personally reviewed this report and concur with its findings and conclusions as amended in the final report, as affirmed by my electronic signature.

Resident/Fellow: [REDACTED] +100

Attending: [REDACTED] +100

Electronically Signed By: [REDACTED] +100

Order Report

☒ Order Details

Order Barcode

[Click to view Order Barcode](#)

[page 8 of 10]
[REDACTED]

[REDACTED]

MyChart Results Release

MyChart Status: Active

Patient Release Status:

This result is viewable by the patient in MyChart.

Last viewed in MyChart:

[REDACTED] +1155

By:

[REDACTED] +1150

Procedure:

CT CHEST, ABDOMEN & PELVIS WITH IV CONTRAST

Exam Date & Time:

[REDACTED] +1150

Status:

Final

Patient:

DOB:

Sex:

Pt Class:

Outpatient

Location:

MRN #:

Order #:

Accession #

Ord Prov:

NARRATIVE:

EXAM:

CT CHEST, ABDOMEN AND PELVIS WITH IV CONTRAST

[REDACTED] +1150

HISTORY:

Restage, metastatic breast cancer. Malignant neoplasm of right female breast. Secondary malignant neoplasm of left lung.

COMPARISON:

CT chest, abdomen and pelvis dated

[REDACTED] +1045

TECHNIQUE:

Following the IV infusion of 125 cc of Isovue 370, postinfusion 3 mm helical acquisitions of chest and 5 mm helical acquisitions of the abdomen/pelvis were obtained. Delayed acquisitions as well as sagittal and coronal reconstructions were obtained.

The CT scan was performed with attention to patient radiation dose reduction, as low as reasonably achievable (ALARA), while maintaining diagnostic image quality. At least one of the

[page 9 of 10]
following dose reduction techniques was used: Automated exposure control, adjustment of the mA and/or kV according to patient size, use of iterative reconstruction technique.

FINDINGS:

CHEST:

Lungs and central airways: Central airways patent. Redemonstrated postsurgical changes in the superior aspect of the left lower lobe. No increased soft tissue or nodularity along the suture line. Interval decreased conspicuity of a subtle ground-glass and streaky opacity within the medial anterior left upper lobe, which likely represent scarring/atelectasis (3/32). Stable linear scarring or atelectasis of the right middle lobe and lingula. No new suspicious pulmonary nodules.

Pleura/ Pleural Space: No pleural effusion.

Mediastinum and Hila: No enlarged mediastinal or hilar lymph nodes.

Heart and pericardium: Heart is normal in size. No pericardial effusion.

Vessels: Thoracic aorta and main pulmonary artery are normal in caliber.

Chest wall: No axillary lymphadenopathy. Interval decrease in size of soft tissue density in the right upper breast measuring 1.7 x 0.9 cm (2/26). Stable punctate calcification or metallic clip in the lower right breast.

Lower Neck: Thyroid gland is nonenlarged. No enlarged supraclavicular lymph nodes.

Support Devices: Left chest Port-A-Cath distal tip reaches the right atrium.

ABDOMEN/PELVIS:

Liver, gallbladder, pancreas, spleen, adrenal glands: Liver parenchyma is homogeneous without focal lesions. Gallbladder, spleen, pancreas and adrenal glands are unremarkable.

Kidneys, ureters, bladder/GU/GYN: Kidneys demonstrate symmetric bilateral enhancement and excretion. No hydronephrosis or hydroureter. No perinephric fluid collection or fat stranding. No enhancing renal lesions. Urinary bladder is mostly decompressed, limiting evaluation. Uterus is anteverted and nonenlarged.

Gastrointestinal tract: Evaluation is suboptimal without oral contrast. No dilated bowel loops. Moderate to large colonic stool burden. No free abdominal fluid or pneumoperitoneum.

Vasculature: Abdominal aorta is non aneurysmal. Origins of the major mesenteric branches are patent.

Lymph nodes: No enlarged abdominopelvic lymph nodes.

Osseous structures: No destructive osseous lesions. Mild multilevel degenerative changes in the spine. Vertebral body heights are maintained.

Soft tissues: Unremarkable.

IMPRESSION:

1. Interval decrease in size of previous right upper breast collection/soft tissue density.

[page 10 of 10]
[REDACTED]

2. Otherwise, no significant interval change since the prior study dated [REDACTED] +1045

I, [REDACTED] have personally reviewed and interpreted the images of this study. In addition, I have personally reviewed this report and concur with its findings and conclusions, as affirmed by my electronic signature.

Resident/Fellow: [REDACTED] +1150

Attending: [REDACTED] +1150

Electronically Signed By: [REDACTED] +1150

Order Report

[Order Details](#)

Order Barcode

[Click to view Order Barcode](#)

Source: NCI Genomic Data Commons file d902b335-6f31-4f6b-bc98-a48d8b9efb8e (ER0513 ER-B1PV Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).